Gene-level copy-number profile of tumor specimen HCM-CSHL-0078-C25-01A from HCMI case HCM-CSHL-0078-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,533 days).
Specimen HCM-CSHL-0078-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9ed3fba2-dbef-46b0-8ce3-0e9f6e77a925.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0078-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,880 have no estimate.
https://portal.gdc.cancer.gov/files/eb565b11-61f2-422a-80ce-fa1fc97feb9f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 524; copy number 1: 2,406; copy number 2: 19,335; copy number 3: 21,395; copy number 4: 7,263; copy number 5: 3,236; copy number 6: 3,134; copy number 7: 252; copy number 8: 370; copy number 9: 176; copy number 10: 72; copy number 11: 12; copy number 12: 14; copy number 13: 45; copy number 14: 69; copy number 15: 156; copy number 17: 104; copy number 20: 24; copy number 23: 8; copy number 24: 37; copy number 26: 16; copy number 28: 95.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–3): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,450 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,078,062–84,238,498, 1 gene, copy number 10 (within-gene range 2–10): PRKACB.
- chr1:84,244,334–84,397,831, 5 genes, copy number 10: NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX.
- chr1:87,620,803–88,685,204, 1 gene, copy number 17 (within-gene range 2–17): PKN2-AS1.
- chr1:88,313,153–88,578,201, 5 genes, copy number 11 (within-gene range 11–17): AL049861.1, RN7SL583P, AC093578.1, AC093578.2, RPL36AP10.
- chr1:93,921,268–94,121,148, 10 genes, copy number 10: CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4.
- chr1:143,419,625–154,870,281, 490 genes, copy number 7–28 (broad region; genes not listed).
- chr1:155,335,268–155,660,245, 14 genes, copy number 12 (within-gene range 6–12): ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5.
- chr1:157,573,747–157,598,085, 1 gene, copy number 11: FCRL4.
- chr1:157,636,300–158,186,427, 15 genes, copy number 13: AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, LINC01704, ELL2P1, CD1D.
- chr1:158,254,424–158,357,553, 5 genes, copy number 11: CD1A, HMGN1P5, CD1C, CD1B, CD1E.
- chr1:159,466,321–162,039,567, 128 genes, copy number 10–15 (within-gene range 3–15) (broad region; genes not listed).
- chr1:163,923,670–164,357,364, 4 genes, copy number 15: U3, NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr1:165,400,922–168,075,843, 67 genes, copy number 17 (within-gene range 2–17) (broad region; genes not listed).
- chr1:168,178,962–169,104,907, 26 genes, copy number 10–17: TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1.
- chr6:25,726,063–28,633,594, 173 genes, copy number 8 (broad region; genes not listed).
- chr6:29,657,002–29,995,314, 38 genes, copy number 8: MOG, ZFP57, ZDHHC20P1, HLA-F, AL645939.1, HLA-F-AS1, RPL23AP1, MICE, AL645939.2, Y_RNA, IFITM4P, AL645939.4, AL645939.5, AL645939.3, HLA-V, HCG4, HLA-P, RPL7AP7, MICG, HLA-G, HCG4P8, AL645929.2, HCP5B, AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U, HLA-A, AL671277.1, HLA-W, MICD, HCG9, DDX39BP2, MCCD1P2.
- chr6:30,005,971–30,009,956, 2 genes, copy number 8 (within-gene range 4–8): HLA-J, AL671277.2.
- chr6:32,439,878–33,457,544, 74 genes, copy number 8–20 (broad region; genes not listed).
- chr6:35,733,867–53,924,125, 391 genes, copy number 7–13 (within-gene range 4–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 71. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
